Somatic mutation profile of tumor specimen CPT000432 (aliquot CPT000432-0011) from CPTAC case 05BR058, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 42.0 years (15,329 days).
Specimen CPT000432: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 769735de-2d96-47a3-ac58-61b999ec9177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000428 (Blood Derived Normal), aliquot CPT000428-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af369dde-f81e-4227-93ae-ee6db77c807e

The open-access MAF lists 143 somatic variants for this specimen: 94 protein-altering or splice-affecting, 26 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 26, Intron 13, Splice Site 6, Nonsense Mutation 5, Splice Region 3, RNA 3, Frame Shift Del 3, 5'UTR 2, In Frame Del 2, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3529G>T p.V1177L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99177124; called by muse, mutect2, varscan2
- ANAPC5 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as rs1016259091; called by muse, mutect2, varscan2
- ANKRD24 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as rs751661084, COSV53671895; called by muse, mutect2, varscan2
- C12orf42 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV59387239; called by muse, mutect2, varscan2
- COL5A1 | c.4852C>G p.L1618V | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs759841015; called by muse, mutect2, varscan2
- FEM1A | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 204/520 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1405428500; called by muse, mutect2, varscan2
- GRB10 | c.1012G>A p.D338N (on ENST00000398812; = p.D292N on NM_001001549.3) | Missense Mutation (SNP) | VAF 325/729 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs201248632, COSV60015820; called by muse, mutect2, varscan2
- KDR | c.703del p.E235Nfs*10 | Frame Shift Del (DEL) | VAF 67/447 reads (15%) | catalogued as COSV55766522; called by mutect2, pindel, varscan2
- LCA5 | c.901C>G p.R301G | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63971334, COSV63972740; called by muse, mutect2, varscan2
- LRTM2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 187/523 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs988240534; called by muse, mutect2, varscan2
- LSM14A | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101471750, COSV70884669; called by muse, varscan2
- MELK | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV53203704; called by muse, mutect2, varscan2
- MON2 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54804885; called by muse, mutect2, varscan2
- MUCL3 | c.962C>G p.T321S (on ENST00000304311; = p.T1197S on NM_080870.4) | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.205); catalogued as COSV100424439; called by muse, mutect2, varscan2
- OR52E2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1226206074; called by muse, mutect2, varscan2
- PADI4 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 234/401 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs201235053; called by muse, mutect2, varscan2
- PLA2G15 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1326364212; called by muse, mutect2, varscan2
- PRTG | c.3291G>C p.Q1097H | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as rs1255692930; called by muse, mutect2, varscan2
- PTPDC1 | c.1324G>C p.D442H (on ENST00000375360 / NM_177995.3; = p.D494H on NM_152422.4) | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs762272290; called by muse, mutect2, varscan2
- RTKN | c.919A>G p.M307V (on ENST00000272430 / NM_001015055.2; = p.M294V on NM_033046.2) | Missense Mutation (SNP) | VAF 144/418 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs368986593; called by muse, mutect2, varscan2
- SEMA6C | c.2215C>T p.H739Y | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs766034148; called by muse, mutect2, varscan2
- SLC26A9 | c.720C>T p.T240= | Splice Region (SNP) | VAF 45/225 reads (20%) | catalogued as rs1025188427; called by muse, mutect2, varscan2
- SLC5A4 | c.1397C>A p.P466Q | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756045412; called by muse, mutect2, varscan2
- SPRR1A | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV61081361; called by muse, mutect2, varscan2
- SUMF2 | c.467G>C p.R156P (on ENST00000652303; = p.R137P on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV51917012; called by muse, mutect2, varscan2
- TMTC2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs138363219; called by muse, mutect2, varscan2
- TP53 | c.315del p.S106Afs*17 | Frame Shift Del (DEL) | VAF 138/245 reads (56%) | catalogued as COSV53637914; called by mutect2, varscan2
- WTIP | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 140/366 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99542444; called by muse, varscan2
- XIRP2 | c.2303G>C p.G768A (on ENST00000628543; = p.G943A on NM_152381.6) | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54682782, COSV54694609; called by muse, mutect2, varscan2
- ABCA10 | c.2875A>C p.K959Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA6 | c.448_460+10delinsTAATG p.X150_splice | Splice Site (DEL) | VAF 31/165 reads (19%) | called by pindel, varscan2*
- AC004922.1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ADCY8 | c.1521G>T p.R507S | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF37 | c.1533C>G p.Y511* | Nonsense Mutation (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- BRWD1 | c.2834T>G p.V945G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- C8orf34 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- C9orf50 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- CATSPERD | c.316T>G p.S106A | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCT5 | c.1498+1G>C p.X500_splice | Splice Site (SNP) | VAF 92/377 reads (24%) | called by muse, mutect2, varscan2
- COL12A1 | c.9044G>T p.G3015V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB2 | c.3217G>C p.D1073H | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS3 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DOCK9 | c.4062-31_4062-4del | Splice Region (DEL) | VAF 49/308 reads (16%) | called by mutect2, pindel, varscan2
- FAM117A | c.997A>C p.S333R | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FAM135B | c.824-2A>C p.X275_splice | Splice Site (SNP) | VAF 60/209 reads (29%) | called by muse, mutect2, varscan2
- FES | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FFAR4 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 98/181 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FNDC3B | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FRMPD3 | c.502-1G>C p.X168_splice | Splice Site (SNP) | VAF 51/155 reads (33%) | called by muse, mutect2, varscan2
- FSIP2 | c.15152T>C p.I5051T | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GALNS | c.1285A>C p.T429P | Missense Mutation (SNP) | VAF 128/726 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GALNT11 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GDPD1 | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- GPR32 | c.471_511del p.A158Lfs*27 | Frame Shift Del (DEL) | VAF 67/542 reads (12%) | called by mutect2, pindel
- GRIN1 | c.2589G>A p.Q863= | Splice Region (SNP) | VAF 78/516 reads (15%) | called by muse, mutect2, varscan2
- H3C3 | c.214dup p.V72Gfs*27 | Frame Shift Ins (INS) | VAF 154/212 reads (73%) | called by mutect2, varscan2
- HDAC10 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 171/549 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); called by muse, varscan2
- IGF1R | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INA | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2
- INSRR | c.3613G>T p.V1205F | Missense Mutation (SNP) | VAF 209/612 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- KNG1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MEIOC | c.2161T>A p.Y721N | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MFSD12 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 75/199 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.30110C>T p.S10037F | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MYBL1 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NAALAD2 | c.625T>G p.L209V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAALAD2 | c.2014C>G p.P672A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NFIC | c.777C>A p.D259E | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NIPBL | c.2630C>G p.S877* | Nonsense Mutation (SNP) | VAF 70/349 reads (20%) | called by muse, mutect2, varscan2
- PLPPR3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PRDM10 | c.2056A>C p.K686Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRICKLE4 | c.686_703del p.R229_D234del (on ENST00000359201; = p.R269_D274del on NM_013397.6) | In Frame Del (DEL) | VAF 30/256 reads (12%) | called by mutect2, varscan2
- REEP3 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RIPK4 | c.2152G>T p.G718C (on ENST00000352483; = p.G670C on NM_020639.3) | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SAP130 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SEMA3F | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 255/409 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SEMA5A | c.3061C>A p.H1021N | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SGSM2 | c.369C>G p.S123R | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SIK2 | c.1519A>T p.S507C | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31A1 | c.2747C>G p.A916G | Missense Mutation (SNP) | VAF 153/768 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- SVEP1 | c.6198G>C p.K2066N | Missense Mutation (SNP) | VAF 108/442 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF25 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 76/504 reads (15%) | called by muse, mutect2, varscan2
- TENM3 | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TMEM184A | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 159/258 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM41A | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TMF1 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- TRIO | c.8047+1G>C p.X2683_splice | Splice Site (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- UBR5 | c.6614G>C p.G2205A | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP26 | c.1313T>C p.F438S | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3HAV1 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF675 | c.1003A>C p.T335P | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- ZNF845 | c.2682_2690del p.K894_F896del | In Frame Del (DEL) | VAF 119/292 reads (41%) | called by mutect2, pindel, varscan2
- AC092143.1 | c.1377G>A p.L459= | Silent (SNP) | VAF 40/1204 reads (3%) | called by muse, mutect2
- ADGRG4 | c.9024G>A p.L3008= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- AFF3 | c.1854G>A p.V618= | Silent (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- CACNA1G | c.2019C>T p.A673= | Silent (SNP) | VAF 63/120 reads (53%) | catalogued as rs528125125, COSV61722859; called by muse, mutect2, varscan2
- CALML3 | c.324C>T p.H108= | Silent (SNP) | VAF 26/651 reads (4%) | catalogued as rs1271709800, COSV59450305; called by muse, mutect2
- COG2 | c.1587A>G p.E529= | Silent (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- DNAH9 | c.7671G>C p.T2557= | Silent (SNP) | VAF 72/129 reads (56%) | called by muse, varscan2
- EVC2 | c.2439C>T p.D813= | Silent (SNP) | VAF 124/558 reads (22%) | catalogued as rs370538823; called by mutect2, varscan2
- FAM120B | c.2199G>A p.T733= | Silent (SNP) | VAF 75/266 reads (28%) | catalogued as rs150094606, COSV99379890; called by muse, varscan2
- FGD6 | c.1014T>C p.T338= | Silent (SNP) | VAF 104/318 reads (33%) | called by muse, mutect2, varscan2
- FMN1 | c.3393A>G p.L1131= (on ENST00000616417 / NM_001277313.2; = p.L908= on NM_001103184.4) | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- GLG1 | c.3114G>T p.L1038= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1184749770; called by muse, mutect2, varscan2
- GUCY1A2 | c.1809G>C p.V603= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- HIP1 | c.1797G>A p.Q599= | Silent (SNP) | VAF 54/306 reads (18%) | called by muse, mutect2, varscan2
- LILRA4 | c.1140C>T p.F380= | Silent (SNP) | VAF 38/796 reads (5%) | catalogued as COSV52492316; called by muse, mutect2
- MUSK | c.1693T>C p.L565= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as rs200787064; called by muse, mutect2, varscan2
- NES | c.3000G>A p.L1000= | Silent (SNP) | VAF 101/621 reads (16%) | catalogued as COSV100958037; called by muse, mutect2, varscan2
- OR13G1 | c.702C>A p.A234= | Silent (SNP) | VAF 66/657 reads (10%) | called by muse, mutect2
- PGM5 | c.813G>A p.L271= | Silent (SNP) | VAF 104/311 reads (33%) | catalogued as COSV67163817; called by muse, varscan2
- PLXNB3 | c.1140T>G p.A380= | Silent (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- PURB | c.894C>T p.S298= | Silent (SNP) | VAF 91/225 reads (40%) | catalogued as COSV67480662; called by muse, mutect2, varscan2
- RAB30 | c.75C>G p.L25= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as rs139755224, COSV99475723; called by muse, mutect2, varscan2
- RTN2 | c.867G>C p.T289= | Silent (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- TAAR5 | c.294C>T p.S98= | Silent (SNP) | VAF 164/349 reads (47%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.348C>A p.A116= | Silent (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- ZNF227 | c.1698C>T p.H566= | Silent (SNP) | VAF 94/251 reads (37%) | catalogued as rs1402947546; called by muse, mutect2, varscan2
- ADGB | c.4818+5469C>G | Intron (SNP) | VAF 12/65 reads (18%) | catalogued as rs1562307044; called by muse, mutect2, varscan2
- ARFGEF1 | c.5129-59T>C | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- C10orf95 | chr10:102452154 C>T | 5'Flank (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- CENPN | chr16:81032615 del ACAGTCAAGGGACCCAGG | 3'Flank (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- DKC1 | c.1259+29T>A | Intron (SNP) | VAF 91/288 reads (32%) | called by muse, mutect2, varscan2
- EIF4A2 | c.771+136G>C | Intron (SNP) | VAF 65/286 reads (23%) | called by muse, mutect2, varscan2
- EML2 | c.1122+123C>T | Intron (SNP) | VAF 173/523 reads (33%) | called by muse, mutect2, varscan2
- FAM149A | c.2248+102T>G | Intron (SNP) | VAF 58/138 reads (42%) | called by muse, mutect2, varscan2
- FCN1 | c.*270_*297del | 3'UTR (DEL) | VAF 64/384 reads (17%) | called by mutect2, varscan2
- IGKV1D-27 | n.233C>A | RNA (SNP) | VAF 248/351 reads (71%) | catalogued as rs1385885987; called by muse, mutect2, varscan2
- KCNIP3 | c.-84G>A | 5'UTR (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- KDM6A | c.162-49C>T | Intron (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- MFSD1 | c.163+88_163+130del | Intron (DEL) | VAF 64/278 reads (23%) | called by mutect2, varscan2
- MIR125B2 | chr21:16590203 C>G | 5'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- MIR518F | n.11T>G | RNA (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2
- NCAM1 | c.2457-1626del | Intron (DEL) | VAF 56/131 reads (43%) | called by mutect2, varscan2
- NT5C2 | c.539+189A>G | Intron (SNP) | VAF 122/203 reads (60%) | called by muse, mutect2, varscan2
- OR2W5 | n.592C>A | RNA (SNP) | VAF 199/974 reads (20%) | called by muse, mutect2, varscan2
- P2RY11 | c.*307G>C | 3'UTR (SNP) | VAF 67/333 reads (20%) | called by muse, mutect2, varscan2
- RBBP4 | c.-62G>A | 5'UTR (SNP) | VAF 12/86 reads (14%) | catalogued as rs896900576; called by muse, mutect2
- SLC6A9 | c.1655-42C>A | Intron (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- TBL2 | c.130+1716C>G | Intron (SNP) | VAF 94/195 reads (48%) | called by muse, mutect2, varscan2
- ZNF778 | c.245-803G>A | Intron (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
